Somatic mutation profile of tumor specimen C3L-04071-01 (aliquot CPT0221200006) from CPTAC case C3L-04071, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 69.3 years (25,328 days).
Specimen C3L-04071-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2fefed71-5bc0-453c-a0ab-a4bb5358bb19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04071-31 (Blood Derived Normal), aliquot CPT0220490002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad080b01-4e38-470d-a049-eb142946a734

The open-access MAF lists 160 somatic variants for this specimen: 117 protein-altering or splice-affecting, 30 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 30, Nonsense Mutation 8, Intron 5, 3'UTR 5, Splice Site 4, Splice Region 2, Frame Shift Del 2, RNA 1, Nonstop Mutation 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 89/714 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879255034, CM055365, CM983444; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553579488, COSV51846923; ClinVar: pathogenic; called by muse, mutect2
- ABCC8 | c.2332C>A p.L778M | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1299193955; called by muse, mutect2, varscan2
- ACAP1 | c.2176G>C p.D726H | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.524); catalogued as COSV99341936; called by muse, mutect2, varscan2
- AGRN | c.5458C>T p.R1820W | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs752720189; called by muse, mutect2
- AKAP12 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 10/223 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs894453490; called by muse, mutect2
- ARHGEF19 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs1230240792; called by muse, mutect2, varscan2
- BCAM | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 47/312 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as rs139289024; called by muse, mutect2, varscan2
- CEP76 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs984234502; called by muse, mutect2, varscan2
- COL6A5 | c.2672C>T p.T891I | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337499139; called by muse, mutect2, varscan2
- CSMD3 | c.10664G>A p.R3555H (on ENST00000297405 / NM_001363185.1; = p.R3386H on NM_052900.3) | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs754753189, COSV99835790; called by muse, mutect2, varscan2
- CSMD3 | c.2247G>T p.W749C (on ENST00000297405 / NM_001363185.1; = p.W645C on NM_052900.3) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99826558; called by mutect2, varscan2
- CT47B1 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 74/196 reads (38%) | catalogued as COSV64890760; called by muse, mutect2, varscan2
- DPEP1 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV55361906; called by muse, mutect2
- DPH1 | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 94/423 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs773810529; called by muse, mutect2, varscan2
- EOMES | c.1541C>G p.P514R | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs1202663970; called by muse, mutect2, varscan2
- FBXL19 | c.1152G>T p.W384C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); catalogued as rs1204709860; called by muse, mutect2, varscan2
- JAKMIP3 | c.2389C>A p.R797S | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200657240; called by muse, mutect2, varscan2
- KLHL33 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs561784003; called by muse, mutect2
- MAP3K10 | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs1337762959; called by muse, mutect2
- MYH8 | c.3470G>T p.G1157V | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101238634; called by muse, mutect2, varscan2
- P2RY8 | c.570G>A p.W190* | Nonsense Mutation (SNP) | VAF 65/250 reads (26%) | catalogued as rs377457659, COSV67177690; called by muse, mutect2, varscan2
- PA2G4 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs200413925; called by muse, mutect2
- PABPC5 | c.93G>T p.E31D | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV57040927; called by muse, mutect2, varscan2
- PABPC5 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100442124; called by muse, mutect2, varscan2
- PCDHA4 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 34/466 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as rs1554124875, COSV63543025; called by muse, mutect2
- PDE6A | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs764611191; called by muse, mutect2, varscan2
- PRICKLE2 | c.2459G>T p.R820L (on ENST00000295902; = p.R764L on NM_198859.4) | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as rs546936479, COSV55768782, COSV99897096; called by muse, mutect2, varscan2
- PTPN2 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 75/487 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs1248980805; called by muse, mutect2, varscan2
- RB1CC1 | c.3540G>C p.Q1180H | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1369395177; called by muse, mutect2
- RBMXL3 | c.2097C>G p.S699R | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as rs1259708023; called by muse, mutect2, varscan2
- RNF113A | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as COSV101007059; called by muse, mutect2, varscan2
- RNMT | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 15/102 reads (15%) | catalogued as COSV100055047; called by muse, mutect2, varscan2
- STAB1 | c.1744G>A p.G582S | Missense Mutation (SNP) | VAF 44/256 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.793); catalogued as rs376126816; called by muse, mutect2, varscan2
- STUB1 | c.329A>G p.Y110C | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as rs1208373115; called by muse, mutect2, varscan2
- TGM6 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 24/745 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV52477270; called by muse, mutect2
- THBS2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV64681758; called by muse, mutect2, varscan2
- TIMELESS | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 52/321 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV57510078; called by muse, mutect2, varscan2
- TLR4 | c.401T>C p.V134A (on ENST00000355622 / NM_138554.5; = p.V94A on NM_003266.4) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748810494; called by muse, mutect2, varscan2
- TP53BP1 | c.1657C>G p.P553A | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs1370738650; called by muse, mutect2
- TRPA1 | c.1364G>T p.S455I | Missense Mutation (SNP) | VAF 22/501 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as COSV100084324; called by muse, mutect2
- UBQLNL | c.353C>A p.T118K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV100974143; called by muse, mutect2, varscan2
- USP42 | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs747842497, COSV60358377; called by muse, mutect2, varscan2
- WASHC5 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 180/550 reads (33%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.473); catalogued as rs886062654, COSV59194337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WNT5B | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 25/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1205804440; called by muse, mutect2
- ZNF513 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 45/410 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.264); catalogued as COSV52010391; called by muse, mutect2, varscan2
- ZNF675 | c.1511G>C p.G504A | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.531); catalogued as COSV100704962; called by muse, mutect2
- ZNF831 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 26/275 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs757969550; called by muse, mutect2
- ADGRF4 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- ARHGEF17 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.157); called by muse, mutect2
- ARHGEF19 | c.1240G>T p.A414S | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ATP2B1 | c.1129+1G>T p.X377_splice | Splice Site (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- ATP2B1 | c.1129G>C p.G377R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- C10orf95 | c.547T>A p.W183R | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C16orf78 | c.183A>C p.K61N | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- CD163L1 | c.1337G>C p.W446S | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CERT1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CFAP46 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CHST8 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- COL19A1 | c.2921G>A p.G974D | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCAF4L2 | c.107T>A p.F36Y | Missense Mutation (SNP) | VAF 48/426 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DOCK1 | c.131-2A>G p.X44_splice | Splice Site (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- DOCK5 | c.1234C>G p.Q412E | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- EYS | c.5047T>A p.L1683M | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- F10 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- FAM20C | c.1331T>C p.V444A | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2
- GALNT13 | c.1669T>A p.*557Rext*39 | Nonstop Mutation (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2
- GAS2L3 | c.1928A>T p.K643I | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLI3 | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 32/460 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.186); called by muse, mutect2
- H4C7 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, varscan2
- HDAC1 | c.1352A>G p.K451R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- HS6ST3 | c.398A>G p.D133G | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- HUNK | c.53del p.G18Afs*24 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, varscan2
- IGKV1D-13 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 45/603 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.491); called by muse, mutect2
- IPO13 | c.2197C>T p.R733W | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ITIH2 | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 28/315 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- KMT2D | c.12082_12113del p.T4028* | Frame Shift Del (DEL) | VAF 68/633 reads (11%) | called by mutect2, pindel*
- KRT6C | c.915G>A p.E305= | Splice Region (SNP) | VAF 42/806 reads (5%) | called by muse, mutect2
- LAMC3 | c.2223T>G p.Y741* | Nonsense Mutation (SNP) | VAF 101/557 reads (18%) | called by muse, mutect2, varscan2
- LYST | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- MAS1L | c.963A>C p.R321S | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- MED12L | c.2305G>C p.G769R | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- MTCH1 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH11 | c.4532C>A p.A1511D | Missense Mutation (SNP) | VAF 89/629 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- MZT2A | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- OGT | c.1167-1G>C p.X389_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2
- OR10A2 | c.720_721dup p.S241Yfs*3 | Frame Shift Ins (INS) | VAF 22/120 reads (18%) | called by mutect2, varscan2
- OR2F2 | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHB6 | c.1961C>A p.A654D | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PHF7 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PHYHD1 | c.435G>A p.K145= | Splice Region (SNP) | VAF 39/261 reads (15%) | called by muse, mutect2, varscan2
- PIK3R1 | c.2027C>G p.A676G (on ENST00000521381 / NM_181523.3; = p.A406G on NM_181504.4) | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.059); called by muse, mutect2
- PRSS8 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 26/497 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PTCHD1 | c.1956G>T p.K652N | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PTPRCAP | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 46/411 reads (11%) | called by muse, mutect2, varscan2
- RARB | c.583C>T p.H195Y (on ENST00000383772 / NM_001290216.2; = p.H188Y on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RHEBL1 | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS2 | c.764A>T p.E255V (on ENST00000666250 / NM_001348490.2; = p.E63V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RTCB | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.102); called by muse, mutect2
- RYR2 | c.6847A>T p.K2283* | Nonsense Mutation (SNP) | VAF 72/342 reads (21%) | called by muse, mutect2, varscan2
- SHISA9 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TAS2R3 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TBX5 | c.1133G>T p.C378F | Missense Mutation (SNP) | VAF 42/618 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TCOF1 | c.2230C>T p.P744S (on ENST00000377797 / NM_001135243.1; = p.P667S on NM_000356.4) | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TGFBR3 | c.622T>G p.Y208D | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TLR2 | c.1507G>A p.V503I | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- TP53 | c.601_606del p.L201_R202del | In Frame Del (DEL) | VAF 71/392 reads (18%) | called by mutect2, pindel, varscan2
- TRIM58 | c.872-1G>T p.X291_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | called by mutect2, varscan2
- TTN | c.8699C>G p.S2900C (on ENST00000591111; = p.S2854C on NM_003319.4) | Missense Mutation (SNP) | VAF 29/189 reads (15%) | PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- UCMA | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- UNC5B | c.890C>A p.T297N | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- USP31 | c.619A>T p.S207C | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13B | c.5279C>G p.S1760* | Nonsense Mutation (SNP) | VAF 57/365 reads (16%) | called by muse, mutect2, varscan2
- VXN | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 45/269 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF446 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- ZNF77 | c.206A>G p.E69G | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.514); called by muse, mutect2
- ZNF98 | c.451A>G p.N151D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- APC2 | c.6144G>A p.A2048= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs1178644910; called by muse, mutect2, varscan2
- APOB | c.5538C>A p.A1846= | Silent (SNP) | VAF 43/209 reads (21%) | called by muse, mutect2, varscan2
- AQP9 | c.627G>C p.L209= | Silent (SNP) | VAF 36/372 reads (10%) | called by muse, mutect2
- ARHGEF26 | c.417G>T p.P139= | Silent (SNP) | VAF 7/183 reads (4%) | catalogued as rs772243867; called by muse, mutect2
- ASPSCR1 | c.570G>A p.S190= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as rs201473706; called by muse, mutect2
- ASTN1 | c.2301G>T p.V767= | Silent (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- BCHE | c.981C>T p.L327= | Silent (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- CBY2 | c.567C>A p.L189= | Silent (SNP) | VAF 46/381 reads (12%) | catalogued as COSV60119864; called by muse, mutect2, varscan2
- CES1 | c.916C>T p.L306= | Silent (SNP) | VAF 52/725 reads (7%) | called by muse, mutect2
- CRISPLD1 | c.1209C>T p.L403= | Silent (SNP) | VAF 13/250 reads (5%) | catalogued as rs1402305742; called by muse, mutect2
- DPH1 | c.1281C>T p.S427= | Silent (SNP) | VAF 93/423 reads (22%) | called by muse, mutect2, varscan2
- FCGBP | c.6825G>A p.P2275= | Silent (SNP) | VAF 66/2310 reads (3%) | catalogued as rs1465074897; called by muse, mutect2
- FGL2 | c.525C>T p.S175= | Silent (SNP) | VAF 35/224 reads (16%) | called by muse, mutect2, varscan2
- GLP2R | c.360A>T p.S120= | Silent (SNP) | VAF 58/250 reads (23%) | called by muse, mutect2, varscan2
- H4C7 | c.21C>A p.A7= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- H6PD | c.708G>A p.R236= | Silent (SNP) | VAF 79/586 reads (13%) | catalogued as COSV66231271; called by muse, mutect2, varscan2
- IL16 | c.246G>A p.E82= | Silent (SNP) | VAF 11/105 reads (10%) | catalogued as COSV100267191; called by muse, mutect2, varscan2
- INTS6 | c.1218G>A p.L406= | Silent (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- ITIH2 | c.1995C>A p.S665= | Silent (SNP) | VAF 28/316 reads (9%) | called by muse, mutect2
- LAMA2 | c.6318T>A p.A2106= | Silent (SNP) | VAF 39/273 reads (14%) | called by muse, mutect2, varscan2
- MTUS2 | c.2136A>G p.G712= | Silent (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- MUC17 | c.3861C>A p.T1287= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV60290508; called by muse, mutect2, varscan2
- MYBL1 | c.2061A>G p.T687= | Silent (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- NOTCH1 | c.429G>A p.P143= | Silent (SNP) | VAF 45/691 reads (7%) | catalogued as rs757406877; called by muse, mutect2
- RHBDL3 | c.45C>T p.A15= | Silent (SNP) | VAF 24/202 reads (12%) | called by muse, mutect2, varscan2
- SERPINA5 | c.283C>T p.L95= | Silent (SNP) | VAF 24/159 reads (15%) | called by muse, mutect2, varscan2
- SLC12A3 | c.2883G>A p.E961= (on ENST00000563236 / NM_001126108.2; = p.E970= on NM_000339.3) | Silent (SNP) | VAF 57/540 reads (11%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.2247T>C p.N749= | Silent (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- WIZ | c.1863G>A p.E621= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1364766940, COSV99653292; called by muse, varscan2
- ZMAT4 | c.606C>T p.I202= | Silent (SNP) | VAF 21/209 reads (10%) | called by muse, mutect2
- AP2A1 | c.2115-132C>T | Intron (SNP) | VAF 55/221 reads (25%) | catalogued as rs1185795488; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+2661G>A | Intron (SNP) | VAF 32/101 reads (32%) | called by muse, mutect2, varscan2
- ARPP21 | c.2032+585del | Intron (DEL) | VAF 14/101 reads (14%) | catalogued as COSV99492592; called by mutect2, pindel, varscan2
- ATR | c.-12C>G | 5'UTR (SNP) | VAF 39/325 reads (12%) | catalogued as rs774385622, COSV100638416; called by muse, mutect2, varscan2
- CRACD | c.120+2887A>T | Intron (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- FAM131A | c.*591T>C | 3'UTR (SNP) | VAF 9/250 reads (4%) | called by muse, mutect2
- FLOT2 | c.132-1620G>C | Intron (SNP) | VAF 45/355 reads (13%) | called by muse, mutect2, varscan2
- FOXP1 | c.*19C>T | 3'UTR (SNP) | VAF 36/260 reads (14%) | catalogued as rs1388301498; called by muse, mutect2, varscan2
- LGI2 | c.*3662T>A | 3'UTR (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- MYADML | n.681C>G | RNA (SNP) | VAF 73/344 reads (21%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.*233T>G | 3'UTR (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- SMARCAD1 | c.*326A>G | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133568030 C>A | 5'Flank (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
